Somatic mutation profile of tumor specimen TCGA-E1-5318-01A (aliquot TCGA-E1-5318-01A-01D-1468-08) from TCGA case TCGA-E1-5318, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 42.1 years (15,372 days).
Specimen TCGA-E1-5318-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af5e481d-e27d-4d7b-99f9-abf2712c1127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5318-10A (Blood Derived Normal), aliquot TCGA-E1-5318-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ac681fb-1583-4ee2-bf8c-b153b52d0b83

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>T p.R172M | Missense Mutation (SNP) | VAF 67/155 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSL | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as COSV66965499; called by muse, mutect2
- ATP7A | c.4252T>G p.Y1418D | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV58448447; called by muse, mutect2
- BRWD1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV60898190; called by muse, mutect2, varscan2
- CDH5 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as rs1218033051, COSV58518244; called by muse, mutect2, varscan2
- CWF19L2 | c.2012A>G p.Q671R | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV56514773; called by muse, mutect2, varscan2
- FSTL5 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV60203532; called by muse, mutect2, varscan2
- IL1RL2 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV51816397; called by muse, mutect2
- KCNU1 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67757307; called by muse, mutect2, varscan2
- KLHL30 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1332191459, COSV59976429; called by muse, mutect2
- KLHL9 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as COSV62921921; called by muse, mutect2, varscan2
- KLK4 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as rs267605602, COSV60676011; called by muse, mutect2
- KNDC1 | c.5051C>T p.A1684V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs749712577, COSV58840290; called by muse, mutect2, varscan2
- KRT33B | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52441330; called by muse, mutect2, varscan2
- KSR2 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs552480492, COSV56675883; called by muse, mutect2, varscan2
- LAMP2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 21/309 reads (7%) | catalogued as COSV52353626; called by muse, mutect2
- LMO7 | c.1907G>A p.G636E (on ENST00000357063; = p.G366E on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58540361; called by muse, mutect2, varscan2
- MAGEB2 | c.674A>T p.E225V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV66781040; called by muse, mutect2, varscan2
- NAIP | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867268567, COSV52001801; called by muse, mutect2, varscan2
- NEB | c.5185A>T p.M1729L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.841); catalogued as COSV51428656, COSV51466051; called by muse, mutect2, varscan2
- OR52B6 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs199604989; called by muse, mutect2, varscan2
- PDHA1 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV63328497; called by muse, mutect2, varscan2
- PGRMC1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54293084; called by muse, mutect2, varscan2
- SELE | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs770008382, COSV60976449, COSV60977628; called by muse, mutect2, varscan2
- SI | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52285273; called by muse, mutect2, varscan2
- SIT1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52399977; called by muse, mutect2, varscan2
- VN1R4 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV100237574; called by muse, mutect2, varscan2
- BCOR | c.724del p.E242Sfs*24 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | called by mutect2, pindel, varscan2
- CIC | c.2324_2330dup p.V778Pfs*155 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- AHNAK | c.2679G>A p.E893= | Silent (SNP) | VAF 285/627 reads (45%) | catalogued as rs1402356300, COSV57217913; called by muse, mutect2, varscan2
- CYP1A1 | c.1401C>G p.V467= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as COSV65697538; called by muse, mutect2, varscan2
- PRODH2 | c.822G>A p.G274= (on ENST00000301175; = p.G198= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV56560441; called by muse, mutect2, varscan2
- MIR498 | n.66A>G | RNA (SNP) | VAF 88/110 reads (80%) | called by muse, mutect2, varscan2
